Gene-level copy-number profile of tumor specimen TCGA-FP-7735-01A from TCGA case TCGA-FP-7735, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 77.3 years (28,232 days).
Specimen TCGA-FP-7735-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.10b11bfe-1462-4a76-ab9b-9c2f3f5614b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FP-7735-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/30847515-2211-4274-aa8a-c1dec93b8c1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 21; copy number 2: 39,337; copy number 3: 1,058; copy number 4: 17,599; copy number 5: 529; copy number 6: 1,192; copy number 7: 4; copy number 8: 8; copy number 13: 13; copy number 18: 19; copy number 21: 4; copy number 23: 3; copy number 28: 5; copy number 37: 8.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:174,631,823–174,632,064, 1 gene: RN7SKP40.
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr20:13,995,369–16,053,197, 1 gene (within-gene range 0–2): MACROD2.
- chr20:14,522,081–15,280,873, 9 genes: AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,751 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:188,671,353–189,666,256, 8 genes, copy number 6: AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73.
- chr1:202,168,051–248,919,946, 1,069 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:123,065,321–123,444,445, 4 genes, copy number 7: AC062020.1, LINC01826, AC073409.2, AC073409.1.
- chr4:179,389,134–180,759,038, 6 genes, copy number 5: AC020551.1, AC021193.1, AC108169.1, AC096747.1, NDUFB5P1, AC104803.1.
- chr9:38,433,696–38,543,880, 1 gene, copy number 5 (within-gene range 2–5): AL390726.5.
- chr9:38,478,471–43,045,120, 134 genes, copy number 5 (broad region; genes not listed).
- chr10:58,999,482–62,096,944, 30 genes, copy number 13–37: LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B.
- chr13:53,207,831–53,801,489, 1 gene, copy number 6 (within-gene range 3–6): AL356295.1.
- chr13:53,815,419–61,199,880, 55 genes, copy number 6–8: LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, AL138997.1, SPATA2P1, RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, AL159156.1, RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3, RNA5SP31, LINC00378, EIF4A1P6, AL161901.1, RNY3P5, LINC01442, MIR3169.
- chr16:88,803,789–90,222,851, 66 genes, copy number 5 (broad region; genes not listed).
- chr17:37,642,947–37,684,252, 1 gene, copy number 23 (within-gene range 4–23): AC243571.2.
- chr17:37,686,431–37,802,788, 2 genes, copy number 23: HNF1B, AC243571.1.
- chr17:39,626,740–45,490,749, 374 genes, copy number 5–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
